Somatic mutation profile of tumor specimen TCGA-BB-4217-01A (aliquot TCGA-BB-4217-01A-11D-2078-08) from TCGA case TCGA-BB-4217, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-BB-4217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c379e94-0efa-41ec-9cce-db55f4a9447d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-4217-10A (Blood Derived Normal), aliquot TCGA-BB-4217-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd5fafe1-19e0-4e5b-b37e-b715c0bef800

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD39 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100450364; called by muse, mutect2, varscan2
- CCDC148 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.38); catalogued as COSV99319940; called by muse, mutect2
- CCN6 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV100036932; called by muse, mutect2
- CD5L | c.597A>C p.K199N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV63822346, COSV63822577; called by muse, mutect2, varscan2
- CWF19L2 | c.2309G>T p.C770F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56522653; called by muse, mutect2
- DNAH5 | c.7169T>G p.V2390G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446547; called by mutect2, varscan2
- EPSTI1 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as COSV100552712; called by muse, mutect2
- ETAA1 | c.287C>G p.P96R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99712641; called by muse, mutect2, varscan2
- GDI2 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs1345876246, COSV101200744; called by muse, mutect2
- HECTD2 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as COSV99978313; called by muse, mutect2
- KPNA4 | c.1174A>T p.I392L | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100515060; called by muse, mutect2, varscan2
- LTBP1 | c.3767G>A p.S1256N (on ENST00000404816 / NM_206943.4; = p.S930N on NM_000627.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99697980; called by muse, mutect2, varscan2
- MGAT4C | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100152766, COSV59837891; called by muse, mutect2, varscan2
- NPY2R | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100279530; called by muse, mutect2, varscan2
- PBRM1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs763078803, COSV56275448, COSV56304983; called by muse, mutect2, varscan2
- PCDHA3 | c.2174C>A p.A725E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV100793242, COSV63543094; called by muse, mutect2
- TAS2R30 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67855941; called by muse, mutect2
- TBC1D9 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV101464285; called by muse, mutect2
- TERT | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309399887, COSV99717151; called by muse, mutect2
- WDR82 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99626671; called by muse, mutect2
- ZBTB34 | c.709A>C p.K237Q | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100043611; called by muse, mutect2
- TMEM38B | c.540dup p.Y181Ifs*27 | Frame Shift Ins (INS) | VAF 6/71 reads (8%) | called by mutect2, pindel
- CNTNAP4 | c.2637G>A p.V879= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs755971369, COSV100270023; called by muse, mutect2, varscan2
- GABRA2 | c.609T>C p.S203= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV100733976; called by muse, mutect2
- PGLYRP2 | c.336G>A p.L112= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99483871; called by muse, mutect2, varscan2
- PMFBP1 | c.2292A>C p.T764= (on ENST00000537465; = p.T759= on NM_031293.3) | Silent (SNP) | VAF 13/223 reads (6%) | catalogued as COSV99400463; called by muse, mutect2
- PRKD1 | c.1476C>T p.F492= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs1050229277, COSV59558823; called by muse, mutect2, varscan2
- ST6GAL1 | c.417C>T p.A139= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs898835666, COSV99398403; called by muse, mutect2, varscan2
- TTF1 | c.1191C>T p.V397= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV100524579; called by muse, mutect2
- KPNA4 | c.1032+363A>G | Intron (SNP) | VAF 15/124 reads (12%) | catalogued as rs907429695, COSV100515061; called by muse, mutect2, varscan2
